Somatic mutation profile of tumor specimen TCGA-CG-5723-01A (aliquot TCGA-CG-5723-01A-11D-1600-08) from TCGA case TCGA-CG-5723, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-CG-5723-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12913934-0d4d-47eb-8c72-2e7822985fa8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-5723-11A (Solid Tissue Normal), aliquot TCGA-CG-5723-11A-02D-1600-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d1d6fbd-d7cb-4631-b119-4480ca39aa61

The open-access MAF lists 2,063 somatic variants for this specimen: 1,584 protein-altering or splice-affecting, 441 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,017, Silent 441, Frame Shift Del 426, Nonsense Mutation 46, Frame Shift Ins 38, Splice Site 25, Intron 21, In Frame Del 18, Splice Region 11, RNA 9, 3'Flank 3, 5'UTR 2.

Variants (750 of 2,063; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGT | c.1290del p.F430Lfs*25 | Frame Shift Del (DEL) | VAF 28/98 reads (29%) | catalogued as rs387906578, CD065661; ClinVar: pathogenic; called by mutect2, varscan2
- ATM | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 25/126 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138398778, CM0910483, COSV53723836, COSV53775938; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATM | c.8432del p.K2811Sfs*46 | Frame Shift Del (DEL) | VAF 33/184 reads (18%) | catalogued as rs587782558; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- AXIN2 | c.1994del p.G665Afs*24 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | catalogued as rs267606674; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- BIVM-ERCC5 | c.4113del p.K1371Nfs*65 | Frame Shift Del (DEL) | VAF 25/88 reads (28%) | catalogued as rs752661599, COSV100863757; ClinVar: pathogenic; called by mutect2, varscan2
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 45/159 reads (28%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CFAP20 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 20/66 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs753911484, COSV52630441; called by muse, mutect2, varscan2
- CHD8 | c.4378C>T p.R1460* (on ENST00000646647 / NM_001170629.2; = p.R1181* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 18/55 reads (33%) | catalogued as rs1454466097, COSV63218976; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CPAMD8 | c.2352del p.R785Efs*32 (on ENST00000651564; = p.R738Efs*32 on NM_015692.5) | Frame Shift Del (DEL) | VAF 9/56 reads (16%) | catalogued as rs756064750; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DNAAF4 | c.583del p.I195* | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | catalogued as rs753649614, CD138279; ClinVar: pathogenic; called by mutect2, varscan2
- EVC2 | c.2653C>T p.R885* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as rs146538906, CM116608; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 71/383 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GCDH | c.1173del p.N392Mfs*9 | Frame Shift Del (DEL) | VAF 24/121 reads (20%) | catalogued as rs754002357; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- IRF6 | c.1137G>A p.W379* | Nonsense Mutation (SNP) | VAF 23/135 reads (17%) | catalogued as rs121434228, CM032592, COSV65419094; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNQ3 | c.1599del p.K533Nfs*6 | Frame Shift Del (DEL) | VAF 36/174 reads (21%) | catalogued as rs762289015, COSV101196388; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2*
- MEN1 | c.1561del p.R521Gfs*43 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as rs767319284, CD972318, CM080439, COSV53644931; ClinVar: pathogenic; called by mutect2, varscan2
- MFRP | c.3del p.H2Tfs*100 (on ENST00000449574; = p.H384Tfs*94 on NM_031433.4) | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | catalogued as rs587776595; ClinVar: pathogenic; called by mutect2, pindel
- MSH6 | c.3261del p.F1088Sfs*2 | Frame Shift Del (DEL) | VAF 30/113 reads (27%) | hotspot (GDC flag); catalogued as rs267608078, COSV99029757; ClinVar: pathogenic; called by mutect2, varscan2
- PPP2R1A | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 16/78 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1057519947, COSV59042211, COSV59042295; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RSPO2 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758888137, COSV52641662; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TBX5 | c.1158del p.S387Afs*7 | Frame Shift Del (DEL) | VAF 11/96 reads (11%) | catalogued as rs1064795870; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- WRN | c.15del p.K5Nfs*15 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs878854133; ClinVar: pathogenic; called by mutect2, varscan2
- A4GNT | c.500A>G p.D167G | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754175702, COSV52628714; called by muse, mutect2, varscan2
- AARS2 | c.2607del p.T871Lfs*13 | Frame Shift Del (DEL) | VAF 29/128 reads (23%) | catalogued as rs771808127, COSV55113098; called by mutect2, pindel, varscan2
- ABCA9 | c.934C>A p.L312M | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV60623074; called by muse, mutect2, varscan2
- ABCB5 | c.432dup p.H145Sfs*12 | Frame Shift Ins (INS) | VAF 14/61 reads (23%) | catalogued as rs1434999011; called by mutect2, pindel, varscan2
- ABCC6 | c.2667G>A p.R889= | Splice Region (SNP) | VAF 43/197 reads (22%) | catalogued as rs1294186563, COSV52742899; called by muse, mutect2, varscan2
- ABCC8 | c.3320C>T p.A1107V | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV56846023, COSV56848532; called by muse, mutect2
- ABCG8 | c.1132G>A p.V378M | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs562447483, COSV55392037; called by muse, mutect2, varscan2
- ABHD17C | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1354181572, COSV51917077; called by muse, mutect2, varscan2
- ABI3BP | c.3100A>G p.R1034G | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52532843; called by muse, mutect2, varscan2
- ABL2 | c.2263C>T p.R755C (on ENST00000502732 / NM_007314.4; = p.R740C on NM_005158.5) | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs377370937; called by muse, mutect2, varscan2
- ABLIM2 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as rs781286682, COSV56402493; called by muse, mutect2, varscan2
- ABLIM3 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as rs747716272, COSV58641823; called by muse, mutect2, varscan2
- AC092143.1 | c.1999C>T p.R667C | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.936); catalogued as COSV59247493, COSV59247824; called by muse, mutect2, varscan2
- ACACA | c.5686G>A p.G1896R | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs996541210; called by muse, mutect2, varscan2
- ACAT2 | c.510del p.K170Nfs*4 | Frame Shift Del (DEL) | VAF 19/99 reads (19%) | catalogued as rs774923207; called by mutect2, pindel, varscan2
- ACIN1 | c.1339del p.A447Lfs*19 | Frame Shift Del (DEL) | VAF 24/136 reads (18%) | catalogued as rs879396950, COSV52972585; called by mutect2, pindel, varscan2
- ACTB | c.881A>G p.Y294C | Missense Mutation (SNP) | VAF 64/272 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV59317927; called by muse, mutect2, varscan2
- ACTL7B | c.965G>A p.C322Y | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.505); catalogued as COSV65927166; called by muse, mutect2, varscan2
- ACTL7B | c.722G>A p.G241D | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65927169; called by muse, mutect2, varscan2
- ACTRT2 | c.1117C>A p.Q373K | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV65759147; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 98/226 reads (43%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADA2 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as rs571235882, COSV52831022; called by muse, mutect2, varscan2
- ADAMTS10 | c.2546C>T p.A849V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs781857217, COSV54353441; called by muse, mutect2, varscan2
- ADAMTS20 | c.2224G>A p.A742T | Missense Mutation (SNP) | VAF 64/283 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs914877431, COSV67129674; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2824T>C p.S942P | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.99); catalogued as COSV54442780; called by muse, mutect2
- ADAP2 | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58295600; called by muse, mutect2, varscan2
- ADAR | c.125A>G p.K42R | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1200104409, COSV52713802; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 28/112 reads (25%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRA2 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as rs751596098, COSV59442407, COSV59448701; called by muse, mutect2, varscan2
- ADGRD1 | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.088); catalogued as rs1389471612, COSV55442341; called by muse, mutect2, varscan2
- ADGRG1 | c.1888T>A p.F630I | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV65635422; called by muse, mutect2, varscan2
- AFAP1L1 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs570213105, COSV57044628; called by muse, mutect2, varscan2
- AGAP2 | c.2243del p.G748Afs*13 (on ENST00000547588 / NM_001122772.2; = p.G412Afs*13 on NM_014770.4) | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | catalogued as COSV57732492; called by pindel, varscan2
- AGAP2 | c.2236G>A p.A746T (on ENST00000547588 / NM_001122772.2; = p.A410T on NM_014770.4) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.171); catalogued as COSV57727580; called by muse, varscan2
- AGAP3 | c.551G>A p.S184N (on ENST00000622464; = p.S220N on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV58994127; called by muse, mutect2, varscan2
- AGAP4 | c.1340T>A p.I447N | Missense Mutation (SNP) | VAF 70/397 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV71164843; called by muse, mutect2, varscan2
- AGBL2 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs777996137, COSV54091180; called by muse, mutect2, varscan2
- AGBL5 | c.1266del p.E424Rfs*44 | Frame Shift Del (DEL) | VAF 75/334 reads (22%) | catalogued as rs747733044, COSV59935415; called by mutect2, pindel, varscan2
- AGPAT1 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs1180646502, COSV61247367; called by muse, mutect2, varscan2
- AHNAK | c.4231G>A p.V1411I | Missense Mutation (SNP) | VAF 117/493 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748532801, COSV57209654; called by muse, mutect2, varscan2
- AIPL1 | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs201875142, COSV51506485; called by muse, mutect2, varscan2
- AIRE | c.967C>A p.L323M | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD971970, COSV52393305; called by muse, mutect2, varscan2
- AK5 | c.227G>A p.R76Q (on ENST00000354567 / NM_174858.3; = p.R50Q on NM_012093.4) | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.859); catalogued as rs751153431, COSV58355247; called by muse, mutect2, varscan2
- AK8 | c.949A>G p.I317V | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.163); catalogued as COSV53752810; called by muse, mutect2, varscan2
- AKNAD1 | c.1632del p.N545Tfs*13 | Frame Shift Del (DEL) | VAF 23/109 reads (21%) | catalogued as COSV62196859; called by mutect2, pindel, varscan2
- ALDH1A2 | c.547A>T p.I183F | Missense Mutation (SNP) | VAF 69/257 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51079554; called by muse, mutect2, varscan2
- ALDH3A1 | c.1334del p.P445Rfs*6 | Frame Shift Del (DEL) | VAF 25/124 reads (20%) | catalogued as rs778623472, COSV56735668; called by mutect2, pindel, varscan2
- ALKBH8 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV52834384; called by muse, mutect2, varscan2
- ALMS1 | c.3173T>C p.V1058A | Missense Mutation (SNP) | VAF 58/242 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV52507162; called by muse, mutect2, varscan2
- ALMS1 | c.7267A>C p.N2423H | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.058); catalogued as COSV52507177; called by muse, mutect2, varscan2
- AMDHD2 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1039735970, COSV53550282; called by muse, mutect2, varscan2
- ANAPC1 | c.1526T>C p.V509A | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV61975237; called by muse, mutect2
- ANK3 | c.3727C>T p.R1243C (on ENST00000280772 / NM_001320874.2; = p.R377C on NM_001149.3) | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55051776; called by muse, mutect2, varscan2
- ANK3 | c.76del p.R26Gfs*21 | Frame Shift Del (DEL) | VAF 25/281 reads (9%) | catalogued as rs1373792937; called by mutect2, pindel
- ANKIB1 | c.3119A>C p.N1040T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.007); catalogued as COSV56060200; called by muse, mutect2, varscan2
- ANKRD50 | c.2342G>A p.G781D | Missense Mutation (SNP) | VAF 45/233 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV72385367; called by muse, mutect2, varscan2
- AOC2 | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765912640, COSV53198732; called by muse, mutect2, varscan2
- APAF1 | c.3673G>A p.V1225M (on ENST00000551964 / NM_181861.2; = p.V1171M on NM_001160.3) | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs201029707; called by muse, mutect2, varscan2
- APC | c.6579del p.V2194Ffs*5 | Frame Shift Del (DEL) | VAF 25/145 reads (17%) | catalogued as rs775076289; called by mutect2, pindel, varscan2
- APC2 | c.3076C>T p.R1026W | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs753909362, COSV52017296; called by muse, mutect2, varscan2
- APLNR | c.239T>C p.V80A | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.336); catalogued as COSV57241990; called by muse, mutect2, varscan2
- APLP1 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.125); catalogued as COSV55702660; called by muse, mutect2, varscan2
- APOB | c.4273T>C p.S1425P | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); catalogued as COSV51930949; called by muse, mutect2, varscan2
- APOBEC2 | c.649_651del p.E217del | In Frame Del (DEL) | VAF 19/118 reads (16%) | catalogued as rs775275042; called by pindel, varscan2
- APOBR | c.2749G>A p.G917R (on ENST00000431282; = p.G926R on NM_018690.4) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs774901408, COSV60489791; called by muse, mutect2
- APPL1 | c.460del p.R154Efs*6 | Frame Shift Del (DEL) | VAF 24/158 reads (15%) | catalogued as rs749401724; called by mutect2, varscan2
- AQP6 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs769879813, COSV59646179; called by muse, mutect2, varscan2
- ARFGAP1 | c.161T>G p.V54G | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62262747; called by muse, mutect2, varscan2
- ARFGAP3 | c.687del p.G230Efs*26 | Frame Shift Del (DEL) | VAF 61/329 reads (19%) | catalogued as rs754931118; called by mutect2, pindel, varscan2
- ARFGEF3 | c.4171G>A p.A1391T | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52454639; called by muse, mutect2
- ARHGAP27 | c.1753C>T p.R585* (on ENST00000428638 / NM_001282290.1; = p.R244* on NM_199282.3) | Nonsense Mutation (SNP) | VAF 10/76 reads (13%) | catalogued as COSV65357432; called by muse, mutect2, varscan2
- ARHGAP32 | c.2098A>G p.T700A (on ENST00000310343 / NM_001378025.1; = p.T351A on NM_014715.4) | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV59845797; called by muse, mutect2, varscan2
- ARHGAP32 | c.1606G>T p.E536* (on ENST00000310343 / NM_001378025.1; = p.E187* on NM_014715.4) | Nonsense Mutation (SNP) | VAF 36/135 reads (27%) | catalogued as COSV59845807; called by muse, mutect2, varscan2
- ARHGAP39 | c.2153A>G p.N718S | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs376730876; called by muse, mutect2, varscan2
- ARHGAP45 | c.3262G>A p.G1088R | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); catalogued as rs760355452, COSV53123774; called by muse, mutect2, varscan2
- ARHGEF2 | c.2414C>T p.A805V (on ENST00000361247 / NM_001162383.2; = p.A777V on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV58108937; called by muse, mutect2
- ARHGEF7 | c.2333C>T p.P778L (on ENST00000646102 / NM_001354046.1; = p.P562L on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/193 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.79); catalogued as COSV54541529; called by muse, mutect2, varscan2
- ARID1B | c.4408G>T p.G1470C | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV51657029; called by muse, mutect2, varscan2
- ARID2 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs896638040, COSV57600821, COSV57606795; called by muse, mutect2, varscan2
- ARID4A | c.1266del p.D423Tfs*2 | Frame Shift Del (DEL) | VAF 23/128 reads (18%) | catalogued as rs776520069; called by mutect2, varscan2
- ARNTL | c.946G>A p.A316T (on ENST00000403290 / NM_001297719.2; = p.A315T on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.103); catalogued as rs1264692349, COSV62986037, COSV62988018; called by muse, mutect2, varscan2
- ARPIN | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs755299674, COSV62589999; called by muse, mutect2, varscan2
- ARSI | c.1427A>G p.D476G | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60817147; called by muse, mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 15/57 reads (26%) | catalogued as rs753865255; called by mutect2, varscan2
- ARSJ | c.1490A>G p.N497S | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59537465; called by muse, mutect2, varscan2
- ASAH2 | c.148del p.S50Qfs*40 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | catalogued as rs772181094; called by mutect2, varscan2
- ASCC3 | c.5456C>T p.A1819V | Missense Mutation (SNP) | VAF 42/230 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs572976132, COSV64973955; called by muse, mutect2, varscan2
- ASCC3 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.039); catalogued as COSV61227485; called by muse, mutect2
- ASIC4 | c.1397G>A p.R466Q (on ENST00000347842 / NM_182847.3; = p.R485Q on NM_018674.6) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs375912777; called by muse, mutect2, varscan2
- ASTE1 | c.556A>G p.I186V | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV53908312; called by muse, mutect2, varscan2
- ATF5 | c.255del p.G86Afs*32 | Frame Shift Del (DEL) | VAF 11/46 reads (24%) | catalogued as rs766479650; called by mutect2, pindel, varscan2
- ATG14 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs761765075, COSV55956079; called by muse, mutect2
- ATG2A | c.1607A>G p.Y536C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV65966311; called by muse, mutect2
- ATG7 | c.950T>C p.V317A | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.601); catalogued as COSV61611838; called by muse, mutect2, varscan2
- ATG9A | c.2467G>A p.V823M | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as rs1227788920, COSV54694655; called by muse, mutect2, varscan2
- ATP10D | c.1940A>C p.E647A | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as COSV56705883; called by muse, mutect2, varscan2
- ATP13A2 | c.348-2A>G p.X116_splice | Splice Site (SNP) | VAF 14/99 reads (14%) | catalogued as COSV58699644; called by muse, mutect2, varscan2
- ATP13A3 | c.3079del p.W1027Gfs*31 | Frame Shift Del (DEL) | VAF 24/111 reads (22%) | catalogued as rs746602775; called by mutect2, varscan2
- ATP1A2 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 69/352 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as rs747283283, COSV63403211; called by muse, mutect2, varscan2
- ATP2A1 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as rs780035425, COSV63920550; called by muse, mutect2, varscan2
- ATP2A2 | c.2693T>C p.M898T | Missense Mutation (SNP) | VAF 68/289 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV57875242; called by muse, mutect2, varscan2
- ATP4A | c.2751+2T>C p.X917_splice | Splice Site (SNP) | VAF 13/87 reads (15%) | catalogued as COSV52867029; called by muse, mutect2, varscan2
- ATP4A | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.553); catalogued as rs145767701, COSV52866100; called by muse, mutect2, varscan2
- ATP6V0A2 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 94/370 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs769927427, COSV57747972; called by muse, varscan2
- ATP6V1A | c.252A>C p.K84N | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV56361687; called by muse, varscan2
- ATP8B4 | c.1742C>T p.T581M | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1280658552, COSV52712847; called by muse, mutect2, varscan2
- AXL | c.1164G>T p.E388D | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as COSV56566391; called by muse, mutect2, varscan2
- B4GALT1 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.127); catalogued as COSV65707814; called by muse, mutect2, varscan2
- BAG6 | c.1169del p.P390Qfs*61 | Frame Shift Del (DEL) | VAF 30/136 reads (22%) | catalogued as rs745882580; called by mutect2, varscan2
- BAIAP3 | c.730T>G p.F244V | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV60979045; called by muse, mutect2, varscan2
- BAZ1B | c.2606G>A p.R869H | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs1554571844, COSV59990166; called by muse, mutect2, varscan2
- BBS4 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 67/298 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as COSV51437369; called by muse, mutect2, varscan2
- BCAR1 | c.2257G>A p.A753T | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (1); PolyPhen probably damaging (0.983); catalogued as rs750624866, COSV50780215; called by muse, mutect2, varscan2
- BCL11B | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV61734782; called by muse, mutect2, varscan2
- BCL9 | c.2000G>A p.R667H | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs782700818, COSV52342778; called by muse, mutect2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 23/63 reads (37%) | catalogued as rs768244116; called by mutect2, pindel
- BCR | c.3214C>T p.R1072C | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as rs780858887, COSV100005984; called by muse, mutect2
- BEND3 | c.1973G>A p.R658H | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs377099257; called by muse, mutect2, varscan2
- BEX2 | c.172G>A p.V58I | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.265); catalogued as rs1470330345, COSV65500828, COSV65500935; called by muse, mutect2, varscan2
- BFAR | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs1206475035, COSV55492975; called by muse, mutect2, varscan2
- BICD2 | c.1094C>T p.T365M | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs374704553; ClinVar: uncertain significance; called by muse, mutect2
- BMP2 | c.691G>T p.A231S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.02); catalogued as COSV66577459; called by muse, mutect2, varscan2
- BRAT1 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV58090968; called by muse, mutect2, varscan2
- BRCA2 | c.10253T>G p.I3418S | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs778034661, COSV58412493; called by muse, mutect2, varscan2
- BRD2 | c.2358_2360del p.S793del | In Frame Del (DEL) | VAF 22/74 reads (30%) | catalogued as rs771196815; called by pindel, varscan2
- BRSK1 | c.1624G>A p.G542S | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.987); catalogued as COSV58664461; called by muse, mutect2
- BSDC1 | c.1225C>T p.Q409* | Nonsense Mutation (SNP) | VAF 24/89 reads (27%) | catalogued as COSV61981785; called by muse, mutect2, varscan2
- BTBD7 | c.173del p.K58Rfs*44 | Frame Shift Del (DEL) | VAF 93/336 reads (28%) | catalogued as rs752512017; called by mutect2, varscan2
- BTNL3 | c.1200del p.S401Afs*7 | Frame Shift Del (DEL) | VAF 25/130 reads (19%) | catalogued as rs757227190; called by pindel, varscan2
- C1QTNF1 | c.590T>C p.L197P | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59261416; called by muse, mutect2, varscan2
- C1QTNF4 | c.118del p.L40Wfs*9 | Frame Shift Del (DEL) | VAF 5/19 reads (26%) | catalogued as rs747640589; called by mutect2, varscan2
- C1orf87 | c.1121A>G p.E374G | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV64596772; called by muse, mutect2, varscan2
- C20orf85 | c.269del p.P90Qfs*19 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | catalogued as rs777635732, COSV100959338, COSV64519981; called by mutect2, pindel, varscan2
- C2orf78 | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV68517151; called by muse, mutect2, varscan2
- CA7 | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as rs1335028612, COSV58156086; called by muse, mutect2
- CABS1 | c.1139C>T p.T380M | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs1042426905, COSV56733309; called by muse, mutect2, varscan2
- CACNA1I | c.4309T>C p.C1437R | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100361698, COSV60804954; called by muse, mutect2, varscan2
- CACNA1I | c.4430G>A p.R1477Q | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as rs748100435, COSV60804979; called by muse, varscan2
- CACNA2D1 | c.3157C>T p.R1053* (on ENST00000356253 / NM_001366867.1; = p.R1041* on NM_000722.4) | Nonsense Mutation (SNP) | VAF 34/154 reads (22%) | catalogued as rs752471498, COSV62376523; called by muse, mutect2, varscan2
- CACNB4 | c.1475A>G p.Y492C | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV52391887; called by muse, mutect2, varscan2
- CACNB4 | c.332T>C p.V111A | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.953); catalogued as COSV52391921; called by muse, mutect2
- CACNG6 | c.626del p.P209Rfs*21 (on ENST00000252729 / NM_145814.1; = p.P138Rfs*21 on NM_031897.2) | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | catalogued as rs745648688, COSV53168096; called by mutect2, pindel, varscan2
- CALCA | c.218_219dup p.G74Rfs*16 | Frame Shift Ins (INS) | VAF 20/120 reads (17%) | catalogued as rs781856512; called by mutect2, varscan2
- CAND1 | c.905T>C p.L302P | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV73338577; called by muse, mutect2, varscan2
- CAPN5 | c.671A>C p.D224A (on ENST00000456580; = p.D184A on NM_004055.5) | Missense Mutation (SNP) | VAF 44/247 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53686958; called by muse, mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | catalogued as rs762770988, COSV62756627; called by mutect2, pindel
- CARD14 | c.808_810del p.E270del | In Frame Del (DEL) | VAF 14/72 reads (19%) | catalogued as rs765237261; called by pindel, varscan2
- CARD6 | c.1016C>T p.T339M | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.463); catalogued as rs566975527, COSV54565417; called by muse, mutect2, varscan2
- CASP10 | c.725A>C p.N242T | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.023); catalogued as COSV53777454; called by muse, mutect2, varscan2
- CASP5 | c.524_525del p.C175* | Frame Shift Del (DEL) | VAF 30/222 reads (14%) | catalogued as rs1430801017; called by pindel, varscan2
- CASP8 | c.723T>A p.N241K (on ENST00000432109 / NM_033355.3; = p.N258K on NM_001228.4) | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV51848794; called by muse, mutect2
- CASR | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 69/258 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs763162046, COSV56136267, COSV56137420; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CBX8 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 87/421 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53936060; called by muse, mutect2, varscan2
- CCDC170 | c.610A>G p.N204D | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV53339282; called by mutect2, varscan2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 22/83 reads (27%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCDC42 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as COSV53448480; called by muse, mutect2, varscan2
- CCDC51 | c.205C>T p.H69Y | Missense Mutation (SNP) | VAF 64/125 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.134); catalogued as COSV56488473; called by muse, mutect2, varscan2
- CCDC73 | c.1913del p.N638Ifs*18 | Frame Shift Del (DEL) | VAF 30/116 reads (26%) | catalogued as rs762553129; called by mutect2, varscan2
- CCDC8 | c.1301C>T p.A434V | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV56772885; called by muse, mutect2, varscan2
- CCDC92 | c.890A>C p.H297P | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.529); catalogued as COSV53019252; called by muse, mutect2, varscan2
- CCKAR | c.391A>G p.N131D | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV55160869; called by muse, mutect2
- CCNB3 | c.2138T>C p.L713S | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as COSV52072000; called by muse, mutect2, varscan2
- CCNB3 | c.3094G>A p.A1032T | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV52072008; called by muse, mutect2, varscan2
- CCNP | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as rs1432248934, COSV55687452; called by muse, mutect2, varscan2
- CDC20 | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs200349485, COSV60521934; called by muse, mutect2, varscan2
- CDC25B | c.381-2A>C p.X127_splice (on ENST00000245960 / NM_021873.3; = p.X113_splice on NM_004358.4) | Splice Site (SNP) | VAF 15/65 reads (23%) | catalogued as COSV99847572; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 32/156 reads (21%) | catalogued as rs762194001; called by mutect2, varscan2
- CDH23 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs121908355, CM074088, COSV99818925; ClinVar: conflicting interpretations of pathogenicity / pathogenic; called by muse, mutect2, varscan2
- CDK5 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52521368; called by muse, varscan2
- CDK5RAP2 | c.5174G>A p.R1725H | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs948437328, COSV62573418; called by muse, mutect2, varscan2
- CDKL3 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs965356641, COSV54740845; called by muse, mutect2
- CDYL | c.1301T>C p.F434S (on ENST00000328908 / NM_001368125.1; = p.F380S on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/226 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59359238; called by muse, mutect2, varscan2
- CDYL | c.1532C>T p.A511V (on ENST00000328908 / NM_001368125.1; = p.A457V on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs1561728211, COSV59359243; called by muse, mutect2, varscan2
- CEBPZ | c.2885-3del | Splice Region (DEL) | VAF 26/100 reads (26%) | catalogued as rs375852685; called by mutect2, varscan2
- CEMIP2 | c.2560G>T p.D854Y | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV65484448; called by muse, mutect2, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 28/142 reads (20%) | catalogued as rs1325731082; called by mutect2, varscan2
- CEP112 | c.1073del p.K358Sfs*6 | Frame Shift Del (DEL) | VAF 50/116 reads (43%) | catalogued as rs769310263; called by mutect2, varscan2
- CEP170 | c.4685C>T p.A1562V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.197); catalogued as COSV60507909; called by muse, mutect2, varscan2
- CEP95 | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs782087429, COSV73608767; called by muse, mutect2
- CFAP206 | c.875T>C p.M292T | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV51533321; called by muse, mutect2, varscan2
- CFAP45 | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as rs147644439, COSV63648668; called by muse, mutect2, varscan2
- CHAC1 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as rs760660762, COSV71436027; called by muse, mutect2, varscan2
- CHD3 | c.2677T>C p.S893P | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57873890; called by muse, mutect2, varscan2
- CHD3 | c.5914_5916del p.K1972del (on ENST00000330494 / NM_001005273.3; = p.K1938del on NM_005852.4) | In Frame Del (DEL) | VAF 35/148 reads (24%) | catalogued as rs768305286; called by pindel, varscan2
- CHD8 | c.5666G>A p.R1889H (on ENST00000646647 / NM_001170629.2; = p.R1610H on NM_020920.4) | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777867742, COSV63036682; called by muse, mutect2, varscan2
- CHRDL2 | c.751+2T>C p.X251_splice | Splice Site (SNP) | VAF 13/54 reads (24%) | catalogued as COSV55222329; called by muse, mutect2, varscan2
- CHRDL2 | c.571C>A p.L191I | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as COSV55222344; called by muse, mutect2, varscan2
- CHRNA3 | c.973G>A p.V325M | Missense Mutation (SNP) | VAF 47/228 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs569381256, COSV58774647; called by muse, mutect2, varscan2
- CHST1 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.047); catalogued as rs780753667, COSV57325575; called by muse, mutect2, varscan2
- CHST2 | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.444); catalogued as COSV58885151; called by muse, mutect2, varscan2
- CHSY3 | c.820T>C p.F274L | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.338); catalogued as COSV59275421; called by muse, mutect2, varscan2
- CILK1 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 60/255 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs901020533, COSV63153887; called by muse, mutect2, varscan2
- CKAP2L | c.97A>T p.N33Y | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV56696103; called by muse, mutect2, varscan2
- CKAP5 | c.439A>C p.T147P | Missense Mutation (SNP) | VAF 38/258 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV56366084; called by muse, varscan2
- CLASP1 | c.359A>G p.D120G | Missense Mutation (SNP) | VAF 63/336 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV55320076; called by muse, mutect2, varscan2
- CLCA4 | c.488G>C p.G163A | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55367432; called by muse, mutect2, varscan2
- CLCN6 | c.1183G>C p.V395L | Missense Mutation (SNP) | VAF 70/292 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV56739187; called by muse, mutect2, varscan2
- CLCNKB | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65160215; called by muse, mutect2, varscan2
- CLDN16 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs752758478, COSV53227282; called by muse, mutect2, varscan2
- CLEC4F | c.1318C>T p.Q440* | Nonsense Mutation (SNP) | VAF 24/108 reads (22%) | catalogued as COSV55478890; called by muse, mutect2, varscan2
- CLIC1 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs1312805192, COSV65209185; called by muse, mutect2, varscan2
- CLPB | c.646+2T>C p.X216_splice | Splice Site (SNP) | VAF 16/61 reads (26%) | catalogued as COSV53628950; called by muse, mutect2, varscan2
- CNGB1 | c.3602C>T p.P1201L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as COSV51899441; called by muse, mutect2, varscan2
- CNNM4 | c.1562G>A p.R521Q | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as rs148365594; called by muse, mutect2, varscan2
- CNOT4 | c.1972G>A p.A658T (on ENST00000541284 / NM_001190850.1; = p.A584T on NM_013316.4) | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.026); catalogued as rs753536301, COSV64157171, COSV64158440; called by muse, mutect2, varscan2
- CNST | c.1960A>G p.S654G | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV63623207; called by muse, mutect2, varscan2
- CNTLN | c.3856G>A p.A1286T | Missense Mutation (SNP) | VAF 46/225 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.082); catalogued as rs201242862, COSV52073557; called by muse, mutect2, varscan2
- CNTN3 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1378266665, COSV55167495, COSV99723162; called by muse, mutect2, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 56/176 reads (32%) | catalogued as rs758676375; called by mutect2, varscan2
- CNTNAP1 | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV52849184; called by muse, mutect2, varscan2
- CNTNAP4 | c.2540C>T p.P847L | Missense Mutation (SNP) | VAF 59/281 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1170966719, COSV56669709; called by muse, mutect2, varscan2
- COBL | c.2110G>A p.G704S | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148062130; called by muse, mutect2, varscan2
- COCH | c.565A>G p.T189A (on ENST00000216361 / NM_001347720.1; = p.T124A on NM_004086.3) | Missense Mutation (SNP) | VAF 45/266 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV53550292; called by muse, mutect2, varscan2
- COL11A1 | c.1635del p.P546Lfs*87 | Frame Shift Del (DEL) | VAF 18/94 reads (19%) | catalogued as COSV100615079, COSV62186140; called by mutect2, pindel, varscan2
- COL12A1 | c.628del p.I210Ffs*9 | Frame Shift Del (DEL) | VAF 62/251 reads (25%) | catalogued as rs757069984; called by mutect2, varscan2
- COL18A1 | c.2615del p.P872Qfs*10 (on ENST00000359759 / NM_130444.3; = p.P637Qfs*10 on NM_030582.4) | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | catalogued as COSV100700816; called by mutect2, pindel
- COL24A1 | c.4200C>A p.F1400L | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV65304555, COSV65306712; called by muse, mutect2, varscan2
- COL27A1 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs766068706, COSV61924368; called by muse, mutect2, varscan2
- COL27A1 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs759104028, COSV61927712; called by muse, mutect2, varscan2
- COL5A2 | c.3497C>A p.A1166D | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.339); catalogued as COSV66408585; called by muse, mutect2, varscan2
- COL6A1 | c.2737G>A p.A913T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as rs141713954; called by mutect2, varscan2
- COL6A5 | c.6527C>T p.A2176V (on ENST00000312481; = p.A2172V on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.039); catalogued as COSV55202703; called by muse, mutect2, varscan2
- COL7A1 | c.3759G>T p.K1253N | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV60393732; called by muse, mutect2, varscan2
- COL9A1 | c.2258C>T p.P753L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as rs763616322, COSV57881786; called by muse, mutect2, varscan2
- COL9A1 | c.848del p.P283Lfs*45 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | catalogued as rs941174282; called by mutect2, pindel, varscan2
- COLEC12 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 62/214 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs555229244, COSV68369775; called by muse, mutect2, varscan2
- CORO6 | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs763588603, COSV61470558; called by muse, mutect2, varscan2
- COX7C | c.29C>T p.T10I | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.773); catalogued as rs756232449, COSV56030679; called by muse, mutect2, varscan2
- CPA6 | c.818A>G p.N273S | Missense Mutation (SNP) | VAF 83/362 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52725739; called by muse, mutect2, varscan2
- CPAMD8 | c.4474G>A p.A1492T (on ENST00000651564; = p.A1445T on NM_015692.5) | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as COSV71596364; called by muse, mutect2, varscan2
- CPD | c.3961T>G p.C1321G | Missense Mutation (SNP) | VAF 88/330 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.991); catalogued as COSV56711970; called by muse, mutect2, varscan2
- CR2 | c.1558C>T p.R520C | Missense Mutation (SNP) | VAF 60/262 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs764276175, COSV65506205; called by muse, mutect2, varscan2
- CRISP1 | c.61A>G p.M21V | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs758721480, COSV59993234; called by muse, mutect2, varscan2
- CRYZL1 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV51676901; called by muse, mutect2, varscan2
- CSF2RB | c.2444T>A p.V815D | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53256766; called by muse, mutect2, varscan2
- CSKMT | c.442C>A p.L148M | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV63472856; called by muse, mutect2, varscan2
- CSMD1 | c.5539A>G p.S1847G (on ENST00000520002; = p.S1846G on NM_033225.6) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59305566, COSV59345901; called by muse, mutect2, varscan2
- CSMD3 | c.1640C>T p.T547M (on ENST00000297405 / NM_001363185.1; = p.T443M on NM_052900.3) | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.893); catalogued as rs780453119, COSV52146436; called by muse, mutect2, varscan2
- CSTF1 | c.1073A>G p.Q358R | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.043); catalogued as COSV53858445; called by muse, mutect2, varscan2
- CSTF2 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.572); catalogued as rs767318301, COSV65893688; called by muse, mutect2, varscan2
- CTCF | c.1655C>A p.P552H | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50464878; called by muse, mutect2
- CTNNA1 | c.1479del p.K493Nfs*31 | Frame Shift Del (DEL) | VAF 106/554 reads (19%) | catalogued as COSV57081469; called by mutect2, pindel, varscan2
- CTNNA1 | c.1761del p.F587Lfs*5 | Frame Shift Del (DEL) | VAF 15/80 reads (19%) | catalogued as rs1273174561; called by mutect2, pindel, varscan2
- CTNNA2 | c.346T>A p.S116T | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.624); catalogued as COSV63557979; called by muse, mutect2, varscan2
- CTNND2 | c.1623T>A p.D541E | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.373); catalogued as COSV58878108; called by muse, mutect2, varscan2
- CTSA | c.990del p.C331Afs*36 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | catalogued as rs758642867; called by mutect2, pindel, varscan2
- CUBN | c.5077C>T p.R1693* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as rs769313368, COSV64707363, COSV64712682; called by muse, mutect2, varscan2
- CUBN | c.4502C>T p.A1501V | Missense Mutation (SNP) | VAF 59/266 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.099); catalogued as rs201587209, COSV64712690; called by muse, mutect2, varscan2
- CUBN | c.964G>A p.V322I | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs575021189, COSV64707019; called by muse, mutect2, varscan2
- CUL7 | c.3605C>T p.A1202V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs762601845, COSV54815030; ClinVar: uncertain significance; called by muse, mutect2
- CXCR5 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs373222312; called by muse, mutect2, varscan2
- CXorf38 | c.584T>A p.I195N | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV59947426; called by muse, mutect2, varscan2
- CYB5D1 | c.86A>T p.N29I | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54679300, COSV54680023; called by muse, mutect2, varscan2
- CYB5R4 | c.741del p.E248Rfs*12 | Frame Shift Del (DEL) | VAF 41/200 reads (21%) | catalogued as rs745836350; called by mutect2, varscan2
- CYC1 | c.276del p.S93Afs*161 | Frame Shift Del (DEL) | VAF 14/65 reads (22%) | catalogued as rs756254049; called by mutect2, pindel
- CYP11A1 | c.738del p.M247Cfs*26 | Frame Shift Del (DEL) | VAF 38/197 reads (19%) | catalogued as COSV51434757; called by mutect2, pindel, varscan2
- CYP1A2 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 48/222 reads (22%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.874); catalogued as rs150893756; called by muse, mutect2, varscan2
- CYP1A2 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs770266566, COSV59659457; called by muse, mutect2, varscan2
- CYP26A1 | c.1418C>T p.T473I | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.61); catalogued as COSV56417708; called by muse, mutect2, varscan2
- CYP4F11 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.114); catalogued as COSV56126416; called by muse, mutect2, varscan2
- CYP7A1 | c.342T>G p.I114M | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.063); catalogued as COSV56963109; called by muse, mutect2, varscan2
- DACH1 | c.1441A>G p.T481A (on ENST00000619232 / NM_001366712.1; = p.T429A on NM_080759.6) | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.175); catalogued as COSV57495222; called by muse, mutect2, varscan2
- DALRD3 | c.848T>C p.V283A (on ENST00000341949 / NM_001009996.3; = p.V116A on NM_018114.5) | Missense Mutation (SNP) | VAF 68/145 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV58244591; called by muse, mutect2, varscan2
- DCD | c.236del p.G79Dfs*5 | Frame Shift Del (DEL) | VAF 30/166 reads (18%) | catalogued as rs758489970; called by mutect2, pindel, varscan2
- DCHS2 | n.5576-1G>A | Splice Site (SNP) | VAF 19/120 reads (16%) | catalogued as COSV61770009; called by muse, mutect2, varscan2
- DCP2 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.138); catalogued as COSV66616702; called by muse, mutect2, varscan2
- DCSTAMP | c.1003G>T p.E335* | Nonsense Mutation (SNP) | VAF 75/339 reads (22%) | catalogued as COSV52577090; called by muse, mutect2, varscan2
- DCTN1 | c.1528G>A p.V510I | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.956); catalogued as rs1341390726, COSV62620164; called by muse, mutect2, varscan2
- DDIT4L | c.283C>T p.L95F | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.548); catalogued as COSV56767159; called by muse, mutect2, varscan2
- DDX27 | c.973+2T>C p.X325_splice | Splice Site (SNP) | VAF 22/56 reads (39%) | catalogued as COSV65629402; called by muse, varscan2
- DEDD2 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs1193280301, COSV60141590; called by muse, mutect2, varscan2
- DEFB129 | c.333del p.F111Lfs*15 | Frame Shift Del (DEL) | VAF 32/184 reads (17%) | catalogued as rs765896284; called by mutect2, pindel, varscan2
- DENND1C | c.1312C>T p.H438Y | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as rs1568394321, COSV57568267; called by muse, mutect2, varscan2
- DENND4A | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV71265570; called by muse, mutect2, varscan2
- DENND4B | c.1994C>T p.P665L | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs368380218; called by muse, mutect2, varscan2
- DEPDC5 | c.1141A>G p.K381E | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV56694792; called by muse, mutect2, varscan2
- DGKK | c.2087A>G p.N696S | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.97); catalogued as COSV65706999; called by muse, mutect2, varscan2
- DHDH | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as rs768908579, COSV55481883; called by muse, mutect2, varscan2
- DHTKD1 | c.2696C>A p.A899D | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53802674; called by muse, mutect2, varscan2
- DHX15 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.041); catalogued as rs1333526601, COSV100391446; called by muse, mutect2, varscan2
- DHX15 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.021); catalogued as COSV61026290; called by muse, mutect2, varscan2
- DHX37 | c.1961_1963del p.S654del | In Frame Del (DEL) | VAF 15/106 reads (14%) | catalogued as rs778553042; called by pindel, varscan2
- DHX40 | c.1873G>A p.A625T | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV52066828; called by muse, mutect2, varscan2
- DHX58 | c.1418G>A p.R473Q | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs551428365, COSV52425232, COSV99288241; called by muse, mutect2, varscan2
- DHX8 | c.3142G>A p.V1048M | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52252146; called by muse, mutect2, varscan2
- DICER1 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.787); catalogued as rs1006363970, COSV58617785; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DIDO1 | c.6326C>T p.A2109V | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as COSV56618430; called by muse, mutect2, varscan2
- DIDO1 | c.4351G>T p.D1451Y | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs746238090, COSV56618444, COSV56629313; called by muse, mutect2, varscan2
- DKK1 | c.230T>C p.I77T | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs758193742, COSV64760118; called by muse, mutect2, varscan2
- DLGAP1 | c.163G>T p.A55S | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59795939; called by muse, mutect2, varscan2
- DLK2 | c.1016dup p.G340Wfs*22 | Frame Shift Ins (INS) | VAF 7/60 reads (12%) | catalogued as rs1323689469; called by mutect2, pindel, varscan2
- DMP1 | c.1497A>C p.K499N | Missense Mutation (SNP) | VAF 70/274 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV56819248; called by muse, mutect2, varscan2
- DMWD | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs1211084583, COSV52177012; called by muse, mutect2, varscan2
- DNAH17 | c.12133G>T p.A4045S | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.418); catalogued as COSV67751956; called by muse, mutect2, varscan2
- DNAH7 | c.11773A>G p.I3925V | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.027); catalogued as COSV56758856; called by muse, mutect2, varscan2
- DOC2A | c.619_621del p.K207del | In Frame Del (DEL) | VAF 15/80 reads (19%) | catalogued as rs1051175353; called by pindel, varscan2
- DOCK2 | c.4696C>A p.L1566M | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56951927; called by muse, mutect2, varscan2
- DOP1B | c.2541del p.F847Lfs*7 | Frame Shift Del (DEL) | VAF 49/213 reads (23%) | catalogued as rs750520568; called by mutect2, pindel, varscan2
- DPF1 | c.841C>T p.R281* | Nonsense Mutation (SNP) | VAF 31/108 reads (29%) | catalogued as COSV62792518; called by muse, mutect2, varscan2
- DPP6 | c.42del p.N15Tfs*2 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | catalogued as COSV68062785; called by mutect2, pindel, varscan2
- DPPA4 | c.274A>G p.N92D | Missense Mutation (SNP) | VAF 51/219 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV59509902; called by muse, mutect2, varscan2
- DSCAML1 | c.5485G>A p.V1829M (on ENST00000321322; = p.V1769M on NM_020693.4) | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.816); catalogued as rs773446818, COSV58387374; called by muse, mutect2, varscan2
- DSCAML1 | c.5129C>T p.P1710L (on ENST00000321322; = p.P1650L on NM_020693.4) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as COSV58387383, COSV58399080; called by muse, mutect2
- DSG4 | c.2171C>T p.T724M | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV57390177; called by muse, mutect2, varscan2
- DSP | c.2719C>T p.R907C | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); catalogued as rs749051278, COSV65792211; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DST | c.17369G>A p.C5790Y (on ENST00000361203 / NM_001374722.1; = p.C3487Y on NM_015548.5) | Missense Mutation (SNP) | VAF 64/345 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.236); catalogued as COSV55007351; called by muse, mutect2, varscan2
- DST | c.4157G>A p.R1386H (on ENST00000361203 / NM_001374722.1; = p.R1060H on NM_001723.6) | Missense Mutation (SNP) | VAF 61/332 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs757972504, COSV55007369; called by muse, mutect2, varscan2
- DST | c.2416G>A p.A806T (on ENST00000361203 / NM_001374722.1; = p.A480T on NM_001723.6) | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV55007405; called by muse, mutect2, varscan2
- DUOX2 | c.4445C>T p.T1482M | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750546082, COSV66534894; called by muse, mutect2, varscan2
- DYRK1B | c.1760C>T p.P587L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs780163777, COSV59913247; called by muse, mutect2, varscan2
- EBF2 | c.1220G>A p.R407K | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV68776992; called by muse, mutect2, varscan2
- EDC4 | c.2059G>A p.A687T | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as COSV59302374; called by muse, mutect2, varscan2
- EGR1 | c.1000del p.H334Tfs*198 | Frame Shift Del (DEL) | VAF 26/135 reads (19%) | catalogued as rs746692720; called by mutect2, pindel, varscan2
- EIF1AY | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.667); catalogued as COSV63727505; called by muse, mutect2
- EIF2B1 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1245638011, COSV53015723; called by muse, mutect2, varscan2
- ELMOD2 | c.13T>G p.L5V | Missense Mutation (SNP) | VAF 71/276 reads (26%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV60270259; called by muse, mutect2, varscan2
- ELMOD3 | c.607+2T>C p.X203_splice | Splice Site (SNP) | VAF 31/166 reads (19%) | catalogued as COSV59772056; called by muse, mutect2, varscan2
- ELOA | c.1394del p.N465Mfs*19 | Frame Shift Del (DEL) | VAF 70/168 reads (42%) | catalogued as rs766700925; called by mutect2, varscan2
- ENTPD7 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs746457576, COSV100978500, COSV65112149; called by muse, mutect2, varscan2
- ENY2 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs750806375, COSV53455799; called by muse, mutect2, varscan2
- EPHA3 | c.2575G>A p.D859N | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV60700552; called by muse, mutect2, varscan2
- EPHA6 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV67567200; called by muse, mutect2, varscan2
- EPHA8 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.089); catalogued as COSV51265528, COSV51282952; called by muse, mutect2, varscan2
- EPHX1 | c.400del p.Q134Sfs*12 | Frame Shift Del (DEL) | VAF 49/227 reads (22%) | catalogued as rs756407271; called by mutect2, pindel, varscan2
- EPN2 | c.1613C>A p.P538H | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59060714; called by muse, mutect2, varscan2
- ERP29 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.977); catalogued as COSV55673563; called by muse, mutect2, varscan2
- ESPNL | c.1583G>A p.S528N | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV58033708; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 16/73 reads (22%) | catalogued as rs775950025; called by mutect2, varscan2
- EVC | c.2842del p.V948Cfs*22 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as COSV53833627; called by mutect2, pindel, varscan2
- EXOC4 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.989); catalogued as rs919867909, COSV54091755; called by muse, mutect2, varscan2
- EXOC7 | c.2015C>T p.A672V (on ENST00000335146 / NM_001145297.4; = p.A590V on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV58035550; called by muse, mutect2, varscan2
- EXT1 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs746080792, COSV65477422; called by muse, mutect2, varscan2
- FAAP100 | c.1952A>G p.Q651R | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as COSV59884721; called by muse, mutect2, varscan2
- FAF2 | c.1158A>G p.V386= | Splice Region (SNP) | VAF 94/454 reads (21%) | catalogued as COSV56130499; called by muse, mutect2, varscan2
- FAM107B | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.558); catalogued as COSV51682362; called by muse, mutect2, varscan2
- FAM111B | c.2017C>T p.R673* | Nonsense Mutation (SNP) | VAF 61/206 reads (30%) | catalogued as rs147236932, COSV59111555; called by muse, mutect2, varscan2
- FAM120A | c.1030+2T>C p.X344_splice | Splice Site (SNP) | VAF 63/326 reads (19%) | catalogued as COSV52903550; called by muse, mutect2, varscan2
- FAM160B1 | c.1522C>T p.P508S | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as COSV65087771; called by muse, mutect2, varscan2
- FAM166B | c.159G>A p.W53* | Nonsense Mutation (SNP) | VAF 32/113 reads (28%) | catalogued as COSV63428264; called by muse, mutect2, varscan2
- FAM20A | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56836326; called by muse, mutect2, varscan2
- FAM222A | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.053); catalogued as rs370934435; called by muse, varscan2
- FAM50B | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1288238703, COSV66654673; called by muse, mutect2, varscan2
- FAM90A1 | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); catalogued as COSV56711318; called by muse, mutect2, varscan2
- FANCE | c.929del p.P310Qfs*54 | Frame Shift Del (DEL) | VAF 26/107 reads (24%) | catalogued as rs587778337; ClinVar: not provided; called by mutect2, pindel, varscan2
- FARS2 | c.199A>G p.T67A | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV51165840; called by muse, mutect2, varscan2
- FASTKD2 | c.1147A>T p.I383F | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV52697872; called by muse, mutect2, varscan2
- FAT4 | c.10679T>C p.F3560S | Missense Mutation (SNP) | VAF 63/314 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58678845; called by muse, mutect2, varscan2
- FAT4 | c.12169T>G p.S4057A | Missense Mutation (SNP) | VAF 61/232 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.909); catalogued as COSV58678865; called by muse, mutect2, varscan2
- FBXO34 | c.1333C>T p.R445* | Nonsense Mutation (SNP) | VAF 68/305 reads (22%) | catalogued as COSV100572004, COSV58254073; called by muse, mutect2, varscan2
- FCN1 | c.586C>A p.L196M | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65662140; called by muse, mutect2, varscan2
- FCRL3 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.817); catalogued as COSV63840636; called by muse, mutect2, varscan2
- FCSK | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs370681598; called by muse, mutect2, varscan2
- FEM1B | c.1433A>T p.D478V | Missense Mutation (SNP) | VAF 65/304 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.254); catalogued as COSV60988267; called by muse, mutect2, varscan2
- FER | c.1796A>G p.Q599R | Missense Mutation (SNP) | VAF 39/233 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV55283213; called by muse, mutect2, varscan2
- FER1L6 | c.1705T>C p.Y569H | Missense Mutation (SNP) | VAF 52/229 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV67549192; called by muse, mutect2, varscan2
- FGD4 | c.1519C>T p.Q507* | Nonsense Mutation (SNP) | VAF 16/58 reads (28%) | catalogued as COSV56782493; called by muse, mutect2, varscan2
- FGD5 | c.2461G>A p.V821M | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1206631746, COSV53240320; called by muse, mutect2, varscan2
- FGF13 | c.460A>G p.T154A | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.221); catalogued as COSV59544334; called by muse, mutect2, varscan2
- FGFBP1 | c.78del p.V27* | Frame Shift Del (DEL) | VAF 30/140 reads (21%) | catalogued as rs144178676; called by mutect2, varscan2
- FGFR1OP2 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as rs144332739; called by muse, mutect2, varscan2
- FGFR4 | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.065); catalogued as rs1405684962, COSV52802173; called by muse, mutect2, varscan2
- FGL1 | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 28/297 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146098986; called by muse, mutect2
- FLII | c.3504-1G>T p.X1168_splice | Splice Site (SNP) | VAF 46/188 reads (24%) | catalogued as COSV57497370; called by muse, mutect2, varscan2
- FLOT2 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs567172028, COSV67528946; called by muse, mutect2, varscan2
- FLT3 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV54049646; called by muse, mutect2, varscan2
- FMN2 | c.521G>T p.R174M | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV60425756; called by muse, mutect2, varscan2
- FMO1 | c.1412A>G p.Y471C | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV61445239; called by muse, mutect2, varscan2
- FNDC3B | c.3165dup p.T1056Hfs*16 | Frame Shift Ins (INS) | VAF 14/80 reads (18%) | catalogued as rs769012096; called by mutect2, varscan2
- FNIP2 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52438595; called by muse, mutect2, varscan2
- FOCAD | c.4131del p.G1378Vfs*12 | Frame Shift Del (DEL) | VAF 16/72 reads (22%) | catalogued as rs887086186, COSV58105885; called by pindel, varscan2
- FOSL2 | c.208A>G p.T70A | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV53103995; called by muse, mutect2, varscan2
- FOXA3 | c.109del p.L37Sfs*5 | Frame Shift Del (DEL) | VAF 30/131 reads (23%) | catalogued as rs1405426085; called by mutect2, pindel, varscan2
- FOXD3 | c.754A>G p.M252V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as COSV64379876, COSV64380210; called by muse, mutect2
- FOXM1 | c.1960del p.L654Wfs*3 | Frame Shift Del (DEL) | VAF 25/139 reads (18%) | catalogued as rs780209186; called by mutect2, pindel, varscan2
- FOXP4 | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs374831070, COSV57219304; called by muse, varscan2
- FOXRED1 | c.1286T>C p.V429A | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as COSV55005901; called by muse, mutect2, varscan2
- FRMD8 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs758310158, COSV58212206; called by muse, mutect2, varscan2
- FRY | c.8654A>G p.D2885G | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV66511099; called by muse, mutect2, varscan2
- FSCN3 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 67/295 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs148605578; called by muse, mutect2, varscan2
- FSIP1 | c.1050+2T>C p.X350_splice | Splice Site (SNP) | VAF 18/111 reads (16%) | catalogued as COSV63224158; called by muse, mutect2, varscan2
- FZD10 | c.1028G>A p.G343D | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57472947; called by muse, mutect2, varscan2
- FZD3 | c.1533del p.H512Mfs*8 | Frame Shift Del (DEL) | VAF 31/164 reads (19%) | catalogued as rs1563404339; called by mutect2, pindel, varscan2
- FZD6 | c.1521del p.F507Lfs*25 | Frame Shift Del (DEL) | VAF 27/139 reads (19%) | catalogued as COSV62470622; called by mutect2, pindel, varscan2
- G2E3 | c.1081del p.T361Lfs*16 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | catalogued as rs751355614, COSV52840527; called by mutect2, varscan2
- GALK2 | c.80A>G p.N27S | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV59100618; called by muse, mutect2, varscan2
- GARRE1 | c.2687+2T>C p.X896_splice | Splice Site (SNP) | VAF 8/39 reads (21%) | catalogued as COSV55098153; called by muse, mutect2, varscan2
- GARS1 | c.2202del p.E735Rfs*13 | Frame Shift Del (DEL) | VAF 15/77 reads (19%) | catalogued as rs1184395419; called by pindel, varscan2
- GAS7 | c.1019G>A p.R340Q (on ENST00000432992 / NM_201433.2; = p.R200Q on NM_003644.3) | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); catalogued as rs1325240094, COSV60432781, COSV60437600; called by muse, mutect2, varscan2
- GAS7 | c.263C>T p.S88L (on ENST00000432992 / NM_201433.2; = p.S28L on NM_201432.2) | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs764521353, COSV60434218; called by muse, mutect2, varscan2
- GATAD2A | c.1735G>A p.A579T | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs768273089, COSV53068416; called by muse, mutect2, varscan2
- GDF5 | c.498dup p.I167Hfs*18 | Frame Shift Ins (INS) | VAF 27/120 reads (23%) | catalogued as rs1368882599; called by mutect2, pindel, varscan2
- GDF6 | c.1346T>C p.V449A | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1203136560, COSV54624196; called by mutect2, varscan2
- GDNF | c.605A>C p.K202T | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58479037; called by muse, mutect2, varscan2
- GDPD3 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs201511312, COSV53772434; called by muse, mutect2, varscan2
- GEN1 | c.76A>C p.T26P | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV58055942, COSV58056070; called by muse, varscan2
- GEN1 | c.1482A>C p.K494N | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV58056081; called by muse, mutect2, varscan2
- GFOD1 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1392419549, COSV64954503; called by muse, mutect2, varscan2
- GFPT2 | c.1147G>A p.V383M | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.35); catalogued as rs774417416, COSV53806218; called by muse, mutect2
- GHSR | c.902G>A p.S301N | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV53838350; called by muse, mutect2, varscan2
- GIT2 | c.474A>C p.Q158H | Missense Mutation (SNP) | VAF 45/203 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV58079860; called by muse, mutect2, varscan2
- GJC2 | c.116C>T p.T39M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1289121163, COSV64512625; called by muse, mutect2, varscan2
- GLB1L2 | c.284+2T>C p.X95_splice | Splice Site (SNP) | VAF 16/98 reads (16%) | catalogued as COSV60278209; called by muse, mutect2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 48/231 reads (21%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GLI2 | c.3046G>A p.E1016K (on ENST00000361492 / NM_001374353.1; = p.E1033K on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1287203228; called by muse, varscan2
- GLI3 | c.746G>A p.S249N | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.17); catalogued as rs922663080, COSV67887126; called by muse, mutect2, varscan2
- GLMN | c.1775G>A p.G592E | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.013); catalogued as COSV64860157; called by muse, mutect2, varscan2
- GLRA3 | c.942A>C p.K314N | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV56859806; called by muse, mutect2, varscan2
- GLUD1 | c.313A>C p.I105L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.107); catalogued as COSV53278120; called by muse, mutect2, varscan2
- GNA11 | c.802T>G p.S268A | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV50018361; called by muse, mutect2, varscan2
- GNAI3 | c.778A>G p.T260A | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63983521; called by muse, mutect2, varscan2
- GNB2 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51940603; called by muse, mutect2, varscan2
- GNGT2 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as rs1172469007, COSV55929816; called by muse, mutect2, varscan2
- GNS | c.1510A>G p.N504D | Missense Mutation (SNP) | VAF 110/442 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV50694301; called by muse, varscan2
- GOLGA4 | c.4045T>A p.S1349T | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.339); catalogued as COSV62710125; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 44/210 reads (21%) | catalogued as rs370114090; called by mutect2, varscan2
- GPN1 | c.52C>T p.H18Y | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs746764478; called by muse, mutect2, varscan2
- GPR158 | c.1228G>A p.V410I | Missense Mutation (SNP) | VAF 89/346 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.206); catalogued as rs757293544, COSV66267946; called by muse, mutect2, varscan2
- GPR158 | c.3116A>C p.N1039T | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.177); catalogued as COSV66267951; called by muse, mutect2, varscan2
- GPR162 | c.992G>A p.R331H (on ENST00000311268 / NM_019858.2; = p.R47H on NM_014449.2) | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50589997; called by muse, mutect2, varscan2
- GPR162 | c.1366C>A p.L456M (on ENST00000311268 / NM_019858.2; = p.L172M on NM_014449.2) | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.737); catalogued as COSV51832291; called by muse, mutect2, varscan2
- GPR39 | c.314C>A p.T105N | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61422446; called by muse, mutect2, varscan2
- GPR52 | c.413A>G p.D138G | Missense Mutation (SNP) | VAF 125/480 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52287386; called by muse, mutect2, varscan2
- GPRASP1 | c.824C>A p.P275H | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV64355280; called by muse, mutect2
- GRHL1 | c.1847C>T p.T616M | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.313); catalogued as rs143356570; called by muse, mutect2, varscan2
- GRIA2 | c.2623G>A p.V875I | Missense Mutation (SNP) | VAF 68/294 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.959); catalogued as COSV52387006; called by muse, mutect2, varscan2
- GRID2 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs748007167, COSV56289899; called by mutect2, varscan2
- GRIK5 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV53477010; called by muse, mutect2, varscan2
- GRIP2 | c.835C>T p.R279W (on ENST00000619221; = p.R182W on NM_001080423.4) | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774133342, COSV56120780; called by muse, varscan2
- GRK2 | c.455A>T p.E152V | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.158); catalogued as COSV57951275; called by muse, mutect2, varscan2
- GRM4 | c.146T>A p.I49N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV65212181; called by muse, mutect2, varscan2
- GRM6 | c.1715G>A p.R572H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.511); catalogued as rs921855440, COSV51438345; called by muse, mutect2, varscan2
- GSDMD | c.768G>A p.W256* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as rs767872685, COSV52796858; called by muse, mutect2
- GSDME | c.1309A>C p.T437P | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV61651372; called by muse, mutect2, varscan2
- GSG1 | c.828C>A p.F276L (on ENST00000651961 / NM_001080555.4; = p.Q282K on NM_031289.5) | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV52193967, COSV52196020; called by muse, mutect2, varscan2
- GTF3C5 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1368204913, COSV59598645, COSV59599420; called by muse, mutect2, varscan2
- GUCY2D | c.2392A>G p.M798V | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV54695575; called by muse, mutect2, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 31/126 reads (25%) | catalogued as COSV54945907; called by mutect2, varscan2
- H2AC16 | c.296G>A p.G99D | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.019); catalogued as COSV58899640; called by muse, mutect2, varscan2
- H3-3A | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV64733899; called by muse, mutect2
- H3C7 | c.128G>T p.R43M | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.331); catalogued as COSV55099652; called by muse, mutect2, varscan2
- HAUS6 | c.2250A>C p.K750N | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV100997748; called by muse, mutect2
- HBE1 | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53079831; called by muse, mutect2, varscan2
- HCAR1 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV63673216; called by muse, mutect2, varscan2
- HCFC1 | c.4862C>A p.A1621D | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV60071172; called by muse, mutect2, varscan2
- HCRTR1 | c.44del p.P15Lfs*63 | Frame Shift Del (DEL) | VAF 36/124 reads (29%) | catalogued as rs768602707; called by mutect2, pindel, varscan2
- HDGFL2 | c.677del p.K226Rfs*45 | Frame Shift Del (DEL) | VAF 17/64 reads (27%) | catalogued as rs1219916331, COSV56682191; called by mutect2, varscan2
- HEATR1 | c.5636C>T p.A1879V | Missense Mutation (SNP) | VAF 73/255 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.456); catalogued as COSV63980416; called by muse, mutect2, varscan2
- HEATR1 | c.5180C>T p.A1727V | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as rs200302789; called by muse, varscan2
- HELZ2 | c.5680G>A p.G1894S (on ENST00000467148 / NM_001037335.2; = p.G1325S on NM_033405.3) | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs868094971, COSV71295696; called by muse, mutect2
- HEPH | c.1294C>T p.R432* (on ENST00000343002; = p.R165* on NM_014799.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 22/47 reads (47%) | catalogued as COSV57961523, COSV57962751; called by muse, mutect2, varscan2
- HEPHL1 | c.2897G>C p.R966T | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV59890902, COSV59892237; called by muse, mutect2, varscan2
- HERC2 | c.10735G>A p.A3579T | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.048); catalogued as rs776601157, COSV55317067; called by muse, mutect2, varscan2
- HERC2 | c.541del p.S181Vfs*85 | Frame Shift Del (DEL) | VAF 29/152 reads (19%) | catalogued as rs1449081007; called by mutect2, pindel, varscan2
- HFM1 | c.3100G>A p.G1034S | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54025078; called by muse, mutect2, varscan2
- HFM1 | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756063767, COSV54025087; called by muse, mutect2, varscan2
- HGF | c.1331A>G p.D444G | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55946831, COSV55947457; called by muse, mutect2, varscan2
- HHIPL2 | c.904G>T p.E302* | Nonsense Mutation (SNP) | VAF 120/600 reads (20%) | catalogued as COSV58564316, COSV58567891; called by muse, varscan2
- HIPK3 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.559); catalogued as COSV57561799; called by muse, mutect2, varscan2
- HIPK3 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1224824771, COSV57561809; called by muse, mutect2, varscan2
- HIVEP3 | c.1660del p.H554Tfs*20 | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | catalogued as rs1558087190; called by mutect2, pindel, varscan2
- HIVEP3 | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV56013113; called by muse, mutect2, varscan2
- HKDC1 | c.1645C>T p.R549W | Missense Mutation (SNP) | VAF 57/223 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs746802271, COSV63576384; called by muse, mutect2, varscan2
- HMOX1 | c.522T>A p.S174R | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV53339497; called by muse, mutect2, varscan2
- HNF4A | c.1264C>T p.R422* | Nonsense Mutation (SNP) | VAF 9/41 reads (22%) | catalogued as rs1413742263, COSV57381479; called by muse, mutect2, varscan2
- HNF4G | c.871C>T p.L291F (on ENST00000354370 / NM_001330561.2; = p.L338F on NM_004133.5) | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV62967020; called by muse, mutect2, varscan2
- HNRNPCL1 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.63); catalogued as rs150230498; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1102C>A p.L368I | Missense Mutation (SNP) | VAF 54/260 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV54561456; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1639C>T p.R547W | Missense Mutation (SNP) | VAF 63/250 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs761865412, COSV57131802; called by muse, mutect2, varscan2
- HOXA1 | c.146G>A p.G49D | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as COSV56065775, COSV56067593; called by muse, mutect2, varscan2
- HOXB1 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs747329214, COSV53316885; called by muse, mutect2, varscan2
- HPDL | c.859T>C p.Y287H | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777360560, COSV58343892; called by muse, mutect2, varscan2
- HRH1 | c.677T>G p.L226R | Missense Mutation (SNP) | VAF 71/177 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.103); catalogued as COSV67955298; called by muse, mutect2, varscan2
- HRNR | c.1801G>A p.G601R | Missense Mutation (SNP) | VAF 92/389 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.655); catalogued as rs377306906, COSV64259482; called by muse, mutect2, varscan2
- HSPA12A | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as rs200867772, COSV65020985; called by muse, mutect2, varscan2
- HTR2B | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 69/319 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.871); catalogued as rs763569593, COSV51449510; called by muse, mutect2, varscan2
- HTR3A | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs139646314; called by muse, mutect2, varscan2
- HUWE1 | c.7892A>G p.Q2631R | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV53341061; called by muse, mutect2, varscan2
- IBTK | c.1019T>G p.I340S | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV60392099; called by muse, mutect2, varscan2
- ICE1 | c.3740del p.N1247Ifs*17 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as COSV99664110; called by mutect2, pindel, varscan2
- IDH2 | c.435del p.T146Lfs*15 | Frame Shift Del (DEL) | VAF 24/135 reads (18%) | catalogued as rs747216375; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- IFI35 | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 75/298 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as COSV55896156; called by muse, mutect2, varscan2
- IGDCC4 | c.534G>T p.K178N | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV61536190, COSV61537644; called by muse, mutect2, varscan2
- IGF1R | c.3913del p.L1305Wfs*45 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as COSV51357705; called by mutect2, varscan2
- IGHV1-2 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 34/149 reads (23%) | catalogued as rs368557039; called by muse, mutect2, varscan2
- IGHV3-13 | c.139A>G p.T47A | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.286); catalogued as rs781924898; called by muse, mutect2, varscan2
- IGSF21 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV52127636; called by muse, mutect2, varscan2
- IGSF21 | c.794T>C p.I265T | Missense Mutation (SNP) | VAF 38/179 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV52129955; called by muse, mutect2, varscan2
- IL12RB1 | c.1354G>A p.V452I | Missense Mutation (SNP) | VAF 39/196 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as rs768241396, COSV59096666; called by muse, mutect2, varscan2
- IL12RB1 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as rs373643598, CM1110709; called by muse, mutect2, varscan2
- IMPG2 | c.814_816del p.E272del | In Frame Del (DEL) | VAF 32/158 reads (20%) | catalogued as rs777176327; called by pindel, varscan2
- INHBA | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs923669088, COSV54220683, COSV99638035; called by muse, mutect2, varscan2
- INMT | c.706C>A p.L236I | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.246); catalogued as COSV50000803, COSV50003393; called by muse, mutect2, varscan2
- INO80D | c.1657C>T p.R553C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1319786184, COSV68958136; called by muse, mutect2, varscan2
- INO80D | c.1396C>T p.H466Y | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); catalogued as COSV68958568; called by muse, mutect2, varscan2
- INPP5F | c.3035C>T p.S1012L | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs754544990, COSV62820619; called by muse, varscan2
- IPP | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.523); catalogued as rs767500416, COSV63432355; called by muse, mutect2, varscan2
- IQGAP1 | c.2822del p.N941Ifs*8 | Frame Shift Del (DEL) | VAF 57/221 reads (26%) | catalogued as rs771739474; called by mutect2, varscan2
- IRF5 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50857148; called by muse, mutect2, varscan2
- IRF7 | c.787C>G p.P263A (on ENST00000397566; = p.P250A on NM_001572.5) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV52753834; called by muse, mutect2, varscan2
- IRS1 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59335120; called by muse, mutect2, varscan2
- IRS4 | c.1772del p.G591Afs*20 | Frame Shift Del (DEL) | VAF 80/190 reads (42%) | catalogued as rs780982673; called by mutect2, varscan2
- ITGA6 | c.681del p.F227Lfs*3 | Frame Shift Del (DEL) | VAF 23/175 reads (13%) | catalogued as COSV99905555; called by mutect2, pindel, varscan2
- ITGAM | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54935825; called by muse, mutect2, varscan2
- ITIH2 | c.548A>G p.Y183C | Missense Mutation (SNP) | VAF 73/285 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64432635; called by muse, mutect2, varscan2
- ITIH2 | c.1312G>A p.V438I | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); catalogued as rs147442256, COSV64432690; called by muse, mutect2, varscan2
- ITPKB | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs1399583186, COSV55259532; called by muse, mutect2, varscan2
- ITPR3 | c.3155G>A p.G1052D | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65407708; called by muse, mutect2, varscan2
- ITPRIP | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV53391157; called by muse, mutect2, varscan2
- IWS1 | c.1930-2A>G p.X644_splice | Splice Site (SNP) | VAF 16/91 reads (18%) | catalogued as COSV54867373, COSV54868449; called by muse, mutect2, varscan2
- IWS1 | c.1900C>T p.R634W | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54866229; called by muse, mutect2, varscan2
- JARID2 | c.1037C>A p.A346D | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.014); catalogued as COSV59187652, COSV59194777; called by muse, mutect2, varscan2
- KALRN | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 43/261 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as rs754069791, COSV53759561; called by muse, mutect2, varscan2
- KAT8 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV54896121; called by muse, mutect2, varscan2
- KATNBL1 | c.358A>G p.T120A | Missense Mutation (SNP) | VAF 10/217 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV56622683; called by muse, mutect2
- KBTBD6 | c.1326dup p.R443Afs*8 | Frame Shift Ins (INS) | VAF 16/132 reads (12%) | catalogued as rs774820321; called by mutect2, varscan2
- KCNA2 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV60369578; called by muse, mutect2, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 22/128 reads (17%) | catalogued as rs754892524; called by mutect2, varscan2
- KCNB2 | c.2283del p.S762Pfs*46 | Frame Shift Del (DEL) | VAF 40/177 reads (23%) | catalogued as COSV73050511; called by mutect2, pindel, varscan2
- KCNE5 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.863); catalogued as COSV64508317; called by muse, mutect2, varscan2
- KCNF1 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.379); catalogued as COSV54462706; called by muse, mutect2, varscan2
- KCNH3 | c.589G>A p.G197R | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.714); catalogued as COSV57790276; called by muse, mutect2, varscan2
- KCNIP3 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV54667376; called by muse, mutect2, varscan2
- KCNJ15 | c.131A>G p.D44G | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.253); catalogued as COSV60810599; called by muse, mutect2, varscan2
- KCNK1 | c.467T>C p.I156T | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV64034847; called by muse, mutect2, varscan2
- KCNN4 | c.194T>G p.I65S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV53455141; called by muse, mutect2, varscan2
- KCTD8 | c.1229G>C p.S410T | Missense Mutation (SNP) | VAF 110/545 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV63587599; called by muse, mutect2, varscan2
- KDM2B | c.1050G>A p.V350= | Splice Region (SNP) | VAF 20/86 reads (23%) | catalogued as COSV65639413; called by muse, mutect2, varscan2
- KDM3B | c.3950del p.P1317Rfs*10 | Frame Shift Del (DEL) | VAF 47/221 reads (21%) | catalogued as rs1561792565; called by mutect2, pindel, varscan2
- KDM4C | c.316G>A p.G106S | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1053562805, COSV67185391; called by muse, mutect2, varscan2
- KDM4C | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs780836880, COSV67185395; called by muse, mutect2, varscan2
- KDM5A | c.3758C>T p.A1253V | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66991669; called by muse, mutect2, varscan2
- KDM5A | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 77/392 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV66991676, COSV66995797; called by muse, mutect2, varscan2
- KDM5B | c.2774A>C p.Q925P | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.393); catalogued as COSV52505341, COSV52506570; called by muse, mutect2, varscan2
- KIAA0100 | c.2924C>T p.A975V | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as rs750706234, COSV66491772; called by muse, mutect2, varscan2
- KIAA1328 | c.383A>G p.E128G | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54451203; called by muse, mutect2
- KIF15 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.771); catalogued as rs145837852; called by muse, mutect2, varscan2
- KIF17 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs758746393, COSV56117312; called by muse, mutect2, varscan2
- KIF1B | c.4380_4382del p.R1462del (on ENST00000377086 / NM_001365952.1; = p.R1416del on NM_015074.3) | In Frame Del (DEL) | VAF 11/75 reads (15%) | catalogued as rs1207624940; called by mutect2, pindel, varscan2
- KIF21B | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs774166442, COSV59755456; called by muse, mutect2, varscan2
- KIF24 | c.116A>G p.D39G | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765563188, COSV61454178; called by muse, mutect2, varscan2
- KIF26B | c.3614G>A p.G1205D | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV63639557; called by muse, mutect2, varscan2
- KIF5C | c.944A>G p.K315R | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.226); catalogued as COSV68480619; called by muse, mutect2, varscan2
- KIFC1 | c.1485G>T p.E495D | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as COSV70822813; called by muse, mutect2, varscan2
- KIFC2 | c.1037G>A p.G346D | Missense Mutation (SNP) | VAF 50/206 reads (24%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.862); catalogued as COSV56760627; called by muse, mutect2, varscan2
- KIR2DL1 | c.925G>A p.V309I | Missense Mutation (SNP) | VAF 123/741 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.089); catalogued as rs748379865, COSV52417259; called by muse, mutect2, varscan2
- KLC2 | c.1700del p.G567Afs*11 | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | catalogued as rs772643711; called by mutect2, pindel, varscan2
- KLHL13 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 48/102 reads (47%) | catalogued as COSV53246405; called by muse, mutect2, varscan2
- KLHL31 | c.312del p.D105Tfs*15 | Frame Shift Del (DEL) | VAF 66/307 reads (21%) | catalogued as rs1227078726; called by mutect2, pindel, varscan2
- KLHL42 | c.1194del p.C399Vfs*44 | Frame Shift Del (DEL) | VAF 56/277 reads (20%) | catalogued as rs749194179; called by mutect2, pindel, varscan2
- KLHL7 | c.302T>C p.F101S (on ENST00000339077 / NM_001031710.3; = p.F53S on NM_018846.5) | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV59160664; called by muse, mutect2, varscan2
- KNSTRN | c.709T>G p.S237A | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV51104298; called by muse, mutect2, varscan2
- KRIT1 | c.143del p.K48Rfs*17 | Frame Shift Del (DEL) | VAF 20/111 reads (18%) | catalogued as rs776245507; called by mutect2, varscan2
- KRT10 | c.990A>C p.E330D | Missense Mutation (SNP) | VAF 30/303 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.434); catalogued as COSV54089188; called by muse, mutect2
- KRT13 | c.1043C>T p.T348M | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs759178223, COSV55839611; called by muse, mutect2, varscan2
- KRT2 | c.709A>G p.K237E | Missense Mutation (SNP) | VAF 75/370 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV59009850; called by muse, mutect2, varscan2
- KRT36 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.091); catalogued as rs368513928; called by mutect2, varscan2
- KRT8 | c.534-1G>T p.X178_splice | Splice Site (SNP) | VAF 40/193 reads (21%) | catalogued as COSV53176736; called by muse, mutect2, varscan2
- KRTAP10-9 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs369270847, COSV59957320; called by muse, mutect2, varscan2
- KRTAP19-5 | c.65G>A p.G22D | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.994); catalogued as rs150866063, COSV61858546; called by mutect2, varscan2
- KYNU | c.447del p.F149Lfs*12 | Frame Shift Del (DEL) | VAF 26/110 reads (24%) | catalogued as rs1422327794; called by mutect2, pindel, varscan2
- L1TD1 | c.1588C>T p.H530Y | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.456); catalogued as COSV63133363; called by muse, mutect2, varscan2
- LAIR1 | c.76C>A p.L26M | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57306725; called by muse, mutect2, varscan2
- LAMB3 | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs375951428; called by muse, mutect2, varscan2
- LAMC2 | c.3416G>A p.R1139Q | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs144652590; called by muse, varscan2
- LAMC3 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754717487, COSV63089945; called by muse, mutect2, varscan2
- LARGE2 | c.1804C>T p.R602W | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs752811574, COSV57652093; called by muse, varscan2
- LARGE2 | c.1867C>T p.P623S | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as COSV57652100; called by muse, varscan2
- LCORL | c.321T>A p.D107E | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as COSV58834341; called by muse, mutect2, varscan2
- LEPR | c.2408C>A p.P803H | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV60751375; called by muse, mutect2, varscan2
- LHX2 | c.209A>G p.D70G | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as COSV65318066; called by muse, mutect2, varscan2
- LILRB3 | c.1661C>T p.T554M (on ENST00000346401; = p.T542M on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs200874692; called by muse, mutect2, varscan2
- LIPK | c.588dup p.A197Cfs*9 | Frame Shift Ins (INS) | VAF 59/392 reads (15%) | catalogued as rs776732749; called by mutect2, pindel, varscan2
- LLGL2 | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51346421; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 31/151 reads (21%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMAN2 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); catalogued as rs759011158, COSV57424202, COSV57424360; called by muse, mutect2, varscan2
- LNX2 | c.1175G>T p.G392V | Missense Mutation (SNP) | VAF 56/216 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60335122; called by muse, mutect2, varscan2
- LPA | c.3629G>A p.G1210D | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.498); catalogued as COSV60299944; called by muse, mutect2, varscan2
- LRBA | c.5005T>C p.S1669P | Missense Mutation (SNP) | VAF 53/230 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV63952646; called by muse, mutect2, varscan2
- LRIT3 | c.1345A>G p.K449E | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV59984370; called by muse, mutect2, varscan2
- LRP1 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as rs201097198, COSV54507021, COSV99677012; called by muse, mutect2, varscan2
- LRP1 | c.12040A>G p.T4014A | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.334); catalogued as COSV54507049; called by muse, varscan2
- LRP1B | c.13101del p.H4368Tfs*4 | Frame Shift Del (DEL) | VAF 29/151 reads (19%) | catalogued as rs751694974; called by mutect2, pindel, varscan2
- LRP2 | c.9256C>T p.R3086C | Missense Mutation (SNP) | VAF 43/211 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs761770923, COSV55548238; called by muse, mutect2, varscan2
- LRRC41 | c.400del p.S134Pfs*116 | Frame Shift Del (DEL) | VAF 17/75 reads (23%) | catalogued as rs1557715031, COSV58440688; called by mutect2, varscan2
- LRRC46 | c.778A>G p.T260A | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV51635430; called by muse, mutect2, varscan2
- LRRC7 | c.1897C>T p.R633C (on ENST00000651989 / NM_001370785.2; = p.R600C on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs201500873, COSV50429219; called by muse, mutect2, varscan2
- LRRK1 | c.2893C>T p.Q965* | Nonsense Mutation (SNP) | VAF 14/61 reads (23%) | catalogued as COSV52607263; called by muse, mutect2, varscan2
- LRRK1 | c.5815G>A p.A1939T | Missense Mutation (SNP) | VAF 66/328 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs765835793, COSV52607298; called by muse, mutect2, varscan2
- LTN1 | c.3341A>G p.E1114G | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as COSV63733459; called by muse, mutect2, varscan2
- LUZP4 | c.426T>A p.N142K | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.451); catalogued as COSV64218658; called by muse, mutect2, varscan2
- LXN | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs746001557, COSV51832015; called by muse, mutect2, varscan2
- LY86 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV57911520; called by muse, varscan2
- LYPD3 | c.419G>A p.C140Y | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54987956; called by muse, mutect2, varscan2
- MACF1 | c.1361T>C p.L454P | Missense Mutation (SNP) | VAF 25/107 reads (23%) | catalogued as COSV58367494; called by muse, mutect2, varscan2
- MACF1 | c.1990C>T p.Q664* | Nonsense Mutation (SNP) | VAF 12/72 reads (17%) | catalogued as COSV58367508; called by muse, mutect2, varscan2
- MACF1 | c.14138T>C p.V4713A (on ENST00000372915; = p.V2646A on NM_012090.5) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | catalogued as COSV57115223; called by muse, mutect2, varscan2
- MAEA | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53261849; called by muse, mutect2, varscan2
- MAMDC4 | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 23/93 reads (25%) | catalogued as rs146167637; called by muse, mutect2, varscan2
- MAN2B2 | c.1837G>A p.V613M | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.063); catalogued as rs751331155, COSV53451973; called by muse, mutect2, varscan2
- MANBA | c.2527G>A p.V843M (on ENST00000642252; = p.V797M on NM_005908.4) | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as rs747236675, COSV56964314; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAP2K1 | c.529C>A p.L177M | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV61069932, COSV61073949; called by muse, mutect2, varscan2
- MAP3K9 | c.2066G>A p.R689H (on ENST00000554752 / NM_001284230.1; = p.R703H on NM_033141.4) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs147124893; called by muse, mutect2, varscan2
- MARK1 | c.2311C>T p.R771C | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65066712; called by muse, mutect2, varscan2
- MAST2 | c.3982C>T p.R1328C | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs749213758, COSV63617440; called by muse, mutect2, varscan2
- MATN1 | c.1372T>C p.C458R | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65650352; called by muse, mutect2
- MATR3 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 61/221 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs1332715729, COSV63076673; called by muse, mutect2, varscan2
- MAVS | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs201823260; called by muse, mutect2, varscan2
- MBD6 | c.1991del p.F664Sfs*11 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as COSV63076955; called by mutect2, pindel, varscan2
- MBL2 | c.218del p.P73Lfs*68 | Frame Shift Del (DEL) | VAF 48/211 reads (23%) | catalogued as rs747467008; called by mutect2, pindel, varscan2
- MCCC2 | c.1198T>C p.F400L | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.911); catalogued as COSV60153948; called by muse, mutect2, varscan2
- MCEE | c.419del p.K140Rfs*6 | Frame Shift Del (DEL) | VAF 26/110 reads (24%) | catalogued as rs776473131; called by mutect2, varscan2
- MCF2L2 | c.1932A>T p.G644= | Splice Region (SNP) | VAF 37/201 reads (18%) | catalogued as COSV61051697; called by muse, mutect2, varscan2
- MCM10 | c.2198A>G p.K733R (on ENST00000484800 / NM_182751.3; = p.K732R on NM_018518.5) | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.068); catalogued as COSV66333724; called by muse, mutect2, varscan2
- MCOLN2 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs145109809; called by muse, mutect2, varscan2
- MCUB | c.661C>A p.L221M | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as COSV54460533; called by muse, mutect2, varscan2
- MDFI | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.109); catalogued as rs1411687221, COSV57821840; called by muse, mutect2
- MED13 | c.3367A>G p.T1123A | Missense Mutation (SNP) | VAF 58/279 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV67262874; called by muse, mutect2, varscan2
- MED13L | c.5984A>G p.H1995R | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV56118148; called by muse, mutect2, varscan2
- MED16 | c.1469A>C p.D490A | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54125028; called by muse, mutect2
- MED23 | c.3291T>A p.F1097L | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63431726; called by muse, mutect2, varscan2
- MED26 | c.1687del p.V563* | Frame Shift Del (DEL) | VAF 15/88 reads (17%) | catalogued as COSV54662140; called by mutect2, pindel, varscan2
- MEGF10 | c.1750C>T p.P584S | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57247692; called by muse, mutect2, varscan2
- MEGF6 | c.4339G>A p.G1447S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs772818015, COSV53888240; called by muse, mutect2, varscan2
- MEGF6 | c.2450G>A p.C817Y | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1386760302, COSV53888248; called by muse, mutect2, varscan2
- MEIS2 | c.1138C>T p.R380W (on ENST00000561208 / NM_170675.5; = p.R360W on NM_002399.3) | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54933480; called by muse, mutect2, varscan2
- MESD | c.632del p.K211Rfs*6 | Frame Shift Del (DEL) | VAF 21/102 reads (21%) | catalogued as rs745891632; called by mutect2, varscan2
- METTL15 | c.82G>A p.V28I | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV57719076; called by muse, mutect2, varscan2
- MEX3A | c.803T>C p.F268S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV68479034; called by muse, mutect2, varscan2
- MFAP4 | c.177del p.S60Rfs*13 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | catalogued as COSV55191843; called by mutect2, pindel, varscan2
- MIA2 | c.1089del p.D364Tfs*8 | Frame Shift Del (DEL) | VAF 15/96 reads (16%) | catalogued as rs538500709; called by mutect2, varscan2
- MIEF2 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.087); catalogued as COSV59901825; called by muse, mutect2, varscan2
- MISP | c.1669C>T p.R557W | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764138676, COSV53119505; called by muse, mutect2, varscan2
- MITF | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1478130504, COSV58881846; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MKX | c.254T>C p.L85P | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65391893; called by muse, varscan2
- MLH1 | c.637del p.V213Wfs*16 | Frame Shift Del (DEL) | VAF 69/186 reads (37%) | catalogued as CM000176; called by mutect2, pindel, varscan2
- MLXIPL | c.2281C>T p.R761C | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as rs782130144, COSV57667645; called by muse, mutect2, varscan2
- MLYCD | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs769856531, COSV52304560; called by muse, mutect2, varscan2
- MMP12 | c.318del p.V108Yfs*18 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | catalogued as rs782219122; called by mutect2, pindel, varscan2
- MMP3 | c.97C>T p.L33F | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.02); catalogued as COSV55405588; called by muse, mutect2, varscan2
- MOB1B | c.567del p.F189Lfs*19 | Frame Shift Del (DEL) | VAF 46/233 reads (20%) | catalogued as rs778232663; called by mutect2, varscan2
- MOGS | c.832_833del p.K278Efs*5 | Frame Shift Del (DEL) | VAF 42/309 reads (14%) | catalogued as rs781260708; called by mutect2, pindel, varscan2
- MON2 | c.2831G>A p.C944Y | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54805497; called by muse, mutect2, varscan2
- MORC1 | c.1137G>A p.M379I | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV51717522; called by muse, mutect2, varscan2
- MPDZ | c.3851A>G p.Q1284R | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.097); catalogued as COSV59916616; called by muse, mutect2, varscan2
- MREG | c.587T>C p.V196A | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV54373366; called by muse, mutect2, varscan2
- MRM2 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV54247872; called by muse, mutect2
- MRPL28 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.819); catalogued as rs1164580442, COSV51738693; called by muse, mutect2, varscan2
- MRPL35 | c.488C>T p.T163M | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1433204791, COSV51256252; called by muse, mutect2, varscan2
- MRPL9 | c.200del p.E67Gfs*32 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as COSV58619003; called by mutect2, pindel, varscan2
- MRPS27 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1286665012, COSV54649695; called by muse, mutect2
- MRTFA | c.1384C>T p.R462* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as rs371934037; called by muse, mutect2, varscan2
- MSANTD3 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs746367895, COSV58492228; called by muse, mutect2
- MTFR1L | c.763_764del p.Q256Rfs*18 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | catalogued as rs1384361947; called by pindel, varscan2
- MTG2 | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372446307; called by muse, mutect2, varscan2
- MTMR3 | c.1700G>A p.R567H | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1313151139, COSV60303127; called by muse, mutect2, varscan2
- MTMR3 | c.2349dup p.R784Qfs*22 | Frame Shift Ins (INS) | VAF 36/200 reads (18%) | catalogued as rs754172179; called by mutect2, varscan2
- MTOR | c.1007A>G p.Y336C | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.52); catalogued as rs1257592579, COSV63869806; called by muse, varscan2
- MTRF1 | c.520C>A p.L174I | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV53480938; called by muse, mutect2
- MXRA5 | c.7354G>A p.V2452M | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs199511755, COSV54231004; called by muse, mutect2, varscan2
- MYBL2 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs750982841, COSV53828963; called by muse, mutect2, varscan2
- MYBPHL | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs143926262; called by muse, mutect2, varscan2
- MYEF2 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs372821159; called by muse, mutect2, varscan2
- MYH10 | c.5537G>A p.R1846H | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1410249872, COSV52598261; called by muse, mutect2, varscan2
- MYH11 | c.5338G>A p.A1780T | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.082); catalogued as COSV55548691; called by muse, mutect2, varscan2
- MYH11 | c.4658A>G p.D1553G | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as COSV55548709; called by muse, mutect2, varscan2
- MYH11 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1452623732, COSV55548723; called by muse, mutect2, varscan2
- MYH14 | c.1172T>C p.M391T | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV51814266; called by muse, mutect2, varscan2
- MYH7 | c.4900C>T p.R1634C | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs397516232, CM050713, COSV62518059; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH7B | c.2796_2798del p.K932del | In Frame Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs764835367; called by pindel, varscan2
- MYL2 | c.3+1G>A p.X1_splice | Splice Site (SNP) | VAF 14/89 reads (16%) | catalogued as COSV99960621; called by muse, mutect2, varscan2
- MYO10 | c.3667G>A p.G1223R | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434873123, COSV57016082, COSV57017061; called by muse, varscan2
- MYO5A | c.2978C>T p.A993V | Missense Mutation (SNP) | VAF 52/216 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV62558688; called by muse, mutect2, varscan2
- MYO6 | c.3536G>A p.R1179H (on ENST00000369981; = p.R1169H on NM_004999.4) | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763284731, COSV64117282; called by muse, mutect2, varscan2
- MYO6 | c.3748C>T p.R1250C (on ENST00000369981; = p.R1240C on NM_004999.4) | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as rs745915772, COSV64118422; called by muse, mutect2, varscan2
- MYOZ1 | c.315C>A p.F105L | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV63771731, COSV63772796; called by muse, mutect2, varscan2
- MZT2A | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs867572181, COSV58311292; called by muse, mutect2
- N4BP1 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs368563685; called by muse, mutect2, varscan2
- NAA16 | c.1890A>T p.E630D | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769875149, COSV65127991; called by muse, mutect2, varscan2
- NAP1L3 | c.1234G>A p.V412I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.56); catalogued as COSV59074686; called by muse, mutect2, varscan2
- NAPA | c.797A>G p.Y266C | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54549535; called by muse, mutect2, varscan2
- NAPEPLD | c.842del p.F281Sfs*14 | Frame Shift Del (DEL) | VAF 36/168 reads (21%) | catalogued as rs746683932, COSV100439928; called by mutect2, varscan2
- NAT2 | c.199T>C p.W67R | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs201345576, COSV54061661; called by muse, mutect2, varscan2
- NAV1 | c.4742G>A p.R1581H | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs369328574; called by muse, mutect2, varscan2
- NBAS | c.4800T>C p.A1600= | Splice Region (SNP) | VAF 28/119 reads (24%) | catalogued as COSV55717539; called by muse, mutect2, varscan2
- NBPF15 | c.1835A>G p.Y612C | Missense Mutation (SNP) | VAF 145/613 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1553538571; called by muse, mutect2, varscan2
- NCAN | c.3445G>A p.D1149N | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53049175; called by muse, mutect2, varscan2
- NCAPH2 | c.1588del p.Q530Sfs*38 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | catalogued as rs1303432981; called by mutect2, pindel, varscan2
- NCDN | c.1430C>A p.P477H | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61935236; called by muse, mutect2, varscan2
- NCK2 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.194); catalogued as COSV51890286; called by muse, mutect2, varscan2
- NCKAP5 | c.3413A>G p.H1138R | Missense Mutation (SNP) | VAF 50/248 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as COSV58437359; called by muse, mutect2, varscan2
- NCOR1 | c.4444C>T p.R1482W | Missense Mutation (SNP) | VAF 86/422 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs1000518180, COSV51963569; called by muse, varscan2
- NDOR1 | c.560del p.T187Rfs*8 | Frame Shift Del (DEL) | VAF 6/45 reads (13%) | catalogued as COSV100789071; called by mutect2, pindel, varscan2
- NEDD9 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.076); catalogued as COSV65220403; called by muse, mutect2, varscan2
- NELFCD | c.791del p.G264Afs*27 (on ENST00000602795; = p.G246Afs*27 on NM_198976.4) | Frame Shift Del (DEL) | VAF 16/77 reads (21%) | catalogued as rs920632659; called by mutect2, pindel, varscan2
- NET1 | c.263G>T p.S88I (on ENST00000355029 / NM_001047160.3; = p.S34I on NM_005863.5) | Missense Mutation (SNP) | VAF 67/330 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV61791153; called by muse, mutect2, varscan2
- NET1 | c.491T>C p.M164T (on ENST00000355029 / NM_001047160.3; = p.M110T on NM_005863.5) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.029); catalogued as rs760269274, COSV61791163; called by muse, mutect2, varscan2
- NEXN | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.033); catalogued as rs755475702, COSV53942473; called by muse, varscan2
- NFIX | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs755556407, COSV62176511; called by mutect2, varscan2
- NGEF | c.333G>A p.M111I | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.001); catalogued as rs769102964, COSV50917772; called by muse, mutect2, varscan2
- NHSL2 | c.1294C>T p.R432W (on ENST00000510661; = p.R798W on NM_001013627.2) | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs144260909, COSV65452950; called by muse, mutect2, varscan2
- NID1 | c.1897C>A p.L633I | Missense Mutation (SNP) | VAF 49/274 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as COSV51618157; called by muse, mutect2, varscan2
- NIPBL | c.4907G>A p.R1636H | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.851); catalogued as COSV56948222; called by muse, mutect2, varscan2
- NKAIN4 | c.157G>T p.G53C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64785339; called by muse, mutect2
- NLGN2 | c.1766T>C p.V589A | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV57209725; called by muse, mutect2, varscan2
- NLRC5 | c.1721G>A p.R574H | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs368370938; called by muse, varscan2
- NLRC5 | c.1742C>T p.A581V | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.186); catalogued as rs748952382, COSV52652752; called by muse, varscan2
- NLRP12 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.362); catalogued as rs749659859, COSV60745823; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOC4L | c.612del p.A205Pfs*13 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | catalogued as rs1402340327; called by mutect2, pindel
- NOS1 | c.3176C>T p.A1059V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as rs56266548, COSV57609926; called by muse, mutect2, varscan2
- NOS3 | c.893A>C p.D298A | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.068); catalogued as COSV52488010; called by muse, mutect2, varscan2
- NOSIP | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs772788289, COSV59197646; called by muse, mutect2, varscan2
- NOSTRIN | c.572del p.N191Tfs*9 (on ENST00000317647 / NM_001039724.4; = p.N113Tfs*9 on NM_052946.3) | Frame Shift Del (DEL) | VAF 27/112 reads (24%) | catalogued as rs1282346576; called by mutect2, pindel, varscan2
- NOTCH2 | c.5657G>A p.R1886H | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1458372923, COSV56684256; called by muse, mutect2, varscan2
- NPAS1 | c.1520C>T p.P507L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs375512462; called by muse, mutect2
- NPBWR1 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV58695862; called by muse, mutect2
- NPC1L1 | c.734A>C p.E245A | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.152); catalogued as COSV56923917; called by muse, mutect2, varscan2
- NPC1L1 | c.296T>C p.L99P | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56923928; called by muse, mutect2, varscan2
- NPEPL1 | c.1534del p.D512Tfs*128 | Frame Shift Del (DEL) | VAF 6/15 reads (40%) | catalogued as COSV61939552; called by mutect2, varscan2
- NPR3 | c.412T>C p.Y138H | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV54085534; called by muse, mutect2, varscan2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 9/76 reads (12%) | catalogued as rs774343392; called by mutect2, varscan2
- NRCAM | c.2587G>A p.E863K (on ENST00000379028 / NM_001371124.1; = p.E847K on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs768851472, COSV61034230, COSV61038743; called by muse, mutect2, varscan2
- NRCAM | c.1758G>T p.R586S (on ENST00000379028 / NM_001371124.1; = p.R580S on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs751996742, COSV61034246; called by muse, mutect2, varscan2
- NRG2 | c.1217T>C p.V406A | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56831725; called by muse, mutect2, varscan2
- NRG3 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.047); catalogued as rs1229338372, COSV64554440; called by muse, mutect2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 25/144 reads (17%) | catalogued as rs776154715; called by mutect2, varscan2
- NRP2 | c.464G>A p.S155N | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV55926228; called by muse, mutect2, varscan2
- NRXN3 | c.1903T>C p.Y635H (on ENST00000557594 / NM_001272020.2; = p.Y1059H on NM_004796.6) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55322499; called by muse, mutect2
- NSD2 | c.3959G>A p.R1320Q | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs773117985, COSV56389094; called by muse, mutect2, varscan2
1,313 further variants in this file (834 protein-altering or splice-affecting, 441 silent, 38 other) are not listed here.
